Gene-level copy-number profile of tumor specimen TCGA-DX-A8BN-01A from TCGA case TCGA-DX-A8BN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.7 years (28,760 days).
Specimen TCGA-DX-A8BN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.19098956-10c1-4bc3-9508-ea862dafa0a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BN-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a64fb46-cfbe-4eac-9d24-f05cdcacb5b4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 128; copy number 2: 11,787; copy number 3: 8,485; copy number 4: 29,876; copy number 5: 4,112; copy number 6: 1,487; copy number 7: 114; copy number 8: 1,773; copy number 9: 204; copy number 10: 382; copy number 11: 278; copy number 12: 1,053; copy number 13: 7; copy number 17: 109.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BN-01A-11D-A37B-01): tumor purity 0.6, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:45,920,366–46,113,928, 14 genes: WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,033 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 9–17 (broad region; genes not listed).
- chr6:167,607–1,101,400, 20 genes, copy number 10 (within-gene range 8–10): AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2.
- chr6:46,220,736–52,840,843, 96 genes, copy number 9 (within-gene range 8–19) (broad region; genes not listed).
- chr6:54,307,859–54,390,142, 2 genes, copy number 11 (within-gene range 4–11): TINAG, TINAG-AS1.
- chr6:54,840,118–56,433,213, 13 genes, copy number 9: AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7.
- chr13:34,910,545–43,181,193, 130 genes, copy number 11 (broad region; genes not listed).
- chr13:43,394,525–43,459,484, 2 genes, copy number 11: RPL36P19, ENOX1-AS2.
- chr17:7,856,685–22,706,703, 557 genes, copy number 12 (broad region; genes not listed).
- chr19:29,287,011–32,829,580, 61 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr19:32,875,925–33,130,542, 7 genes, copy number 13 (within-gene range 2–13): CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1.
- chr19:34,788,527–42,652,355, 435 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
